APOLLO case AP-JK59 — APOLLO1: Proteogenomic characterization of lung adenocarcinoma (APOLLO-LUAD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Adenomas and Adenocarcinomas; Primary site: Bronchus and lung. Index date: not stated by GDC for this case (day counts are relative to an unstated reference).
https://portal.gdc.cancer.gov/cases/74d0e299-cdeb-424a-ad62-776c1736a969

Demographics
Sex at birth: female; Race: white; Vital status: Dead.

Diagnoses (1)
1. Solid carcinoma, NOS: ICD-O-3 morphology code: 8230/3; Tissue or organ of origin: Lung, NOS; Site of resection or biopsy: Lower lobe, lung; AJCC pathologic T: T1b; AJCC pathologic N: N0; AJCC pathologic M: M0; AJCC pathologic stage: Stage IA; Tumor grade: G3; Days to last follow up: 1,070 days (2.9 years).

Exposures
- Tobacco smoking status: Current Smoker; Pack years smoked: 34.

Biospecimens (2 samples)
- Sample AP-JK59-FL: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood Components NOS; Preservation method: Frozen.
- Sample AP-JK59-NN: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
